Somatic mutation profile of tumor specimen C3L-05239-05 (aliquot CPT0346710006) from CPTAC case C3L-05239, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.3 years (14,364 days).
Specimen C3L-05239-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 685b2c9f-7f37-47f9-964c-2eef1f929933.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05239-31 (Blood Derived Normal), aliquot CPT0346770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83f5ef24-13fd-43d3-9425-83f4f5237bbd

The open-access MAF lists 78 somatic variants for this specimen: 52 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 22, Nonsense Mutation 5, Intron 4, In Frame Del 2, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750505698, COSV51561810; called by muse, mutect2, varscan2
- AICDA | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV57563789, COSV57564692; called by muse, mutect2, varscan2
- ANO1 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as rs370304912, COSV60281545; called by muse, mutect2, varscan2
- CHST13 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1272857221; called by muse, mutect2, varscan2
- COL2A1 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 129/377 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1260980345; called by muse, mutect2, varscan2
- CPS1 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV51826330; called by muse, mutect2, varscan2
- DNAH8 | c.12190C>T p.R4064* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as rs1029171985; called by muse, mutect2
- DVL1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs759810718; called by muse, mutect2, varscan2
- EXOC3L1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs146438233, COSV52048430; called by muse, mutect2, varscan2
- GPR132 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1166980456, COSV61677901; called by muse, mutect2
- GPR45 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV51525412; called by muse, mutect2
- HECW2 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 31/163 reads (19%) | catalogued as rs367683245; called by muse, mutect2
- HRNR | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 119/310 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs141928962; called by muse, mutect2, varscan2
- HSP90AA1 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1463905518, COSV53489134; called by muse, mutect2, varscan2
- KRT75 | c.777C>T p.D259= | Splice Region (SNP) | VAF 55/172 reads (32%) | catalogued as rs373953042; called by muse, mutect2, varscan2
- LILRB4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs775772819; called by mutect2, varscan2
- LRP2 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs763860226, COSV55542058; called by muse, mutect2, varscan2
- MACIR | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV60634920; called by muse, mutect2, varscan2
- NYNRIN | c.3481C>T p.R1161C | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777661158, COSV66840935; called by muse, mutect2, varscan2
- PCDHA1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 16/556 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV100974422, COSV65373288; called by muse, mutect2
- PCSK7 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs764759455; called by muse, mutect2
- PPP1R9A | c.1956G>A p.M652I | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56888533; called by muse, mutect2, varscan2
- SLC30A5 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.122); catalogued as rs540142133; called by muse, mutect2, varscan2
- SLC9A8 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs908605614, COSV64289553; called by muse, mutect2, varscan2
- TLCD2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs1434771328; called by muse, mutect2
- TLR10 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs200661388; called by muse, mutect2, varscan2
- TOP3A | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV100329420; called by muse, mutect2, varscan2
- ZNF263 | c.1482G>C p.E494D | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as rs1409070500; called by muse, mutect2
- ZSCAN1 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.835); catalogued as rs764113791, COSV56601539, COSV56605865; called by mutect2, varscan2
- ADAM19 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- B3GALT4 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CARMIL1 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CLASP2 | c.2534_2536del p.D845del | In Frame Del (DEL) | VAF 63/214 reads (29%) | called by mutect2, pindel, varscan2
- EPHA3 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GK2 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MRC1 | c.2926G>C p.A976P | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- MTHFR | c.646_648del p.E216del | In Frame Del (DEL) | VAF 64/212 reads (30%) | called by mutect2, pindel, varscan2
- MYH15 | c.511dup p.H171Pfs*8 | Frame Shift Ins (INS) | VAF 25/139 reads (18%) | called by mutect2, pindel, varscan2
- PDYN | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3R1 | c.451A>T p.R151* | Nonsense Mutation (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.7900C>T p.Q2634* | Nonsense Mutation (SNP) | VAF 114/226 reads (50%) | called by muse, mutect2, varscan2
- RGSL1 | c.3163G>C p.V1055L | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEM1 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SERPINB12 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.255); called by muse, mutect2
- SHCBP1 | c.740A>C p.Y247S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SHOC2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC7A10 | c.1323C>G p.S441R | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX21 | c.112_113del p.I38Qfs*90 | Frame Shift Del (DEL) | VAF 193/524 reads (37%) | called by mutect2, pindel, varscan2
- SUFU | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 107/203 reads (53%) | called by muse, mutect2, varscan2
- TRIM10 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- VPS37C | c.587C>G p.P196R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2
- ZNF562 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- ARHGEF28 | c.4599C>T p.H1533= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1258350405, COSV55252561; called by muse, mutect2, varscan2
- CCT4 | c.891C>T p.V297= | Silent (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- F2 | c.279G>A p.A93= | Silent (SNP) | VAF 53/146 reads (36%) | catalogued as rs778280660, COSV61316709; called by muse, mutect2, varscan2
- FNDC1 | c.2367C>T p.H789= | Silent (SNP) | VAF 70/270 reads (26%) | catalogued as COSV51945075; called by muse, mutect2, varscan2
- GALK1 | c.219G>T p.V73= | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- GRAMD1A | c.1671G>A p.R557= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs932234053; called by muse, mutect2, varscan2
- GRIK1 | c.2460C>T p.P820= | Silent (SNP) | VAF 108/374 reads (29%) | catalogued as rs772381951; called by muse, mutect2, varscan2
- HTR4 | c.936C>T p.Y312= | Silent (SNP) | VAF 59/183 reads (32%) | catalogued as rs376241160; called by muse, mutect2, varscan2
- KIF1A | c.669C>T p.I223= | Silent (SNP) | VAF 66/173 reads (38%) | catalogued as rs752564183; called by muse, mutect2, varscan2
- MAVS | c.1467G>A p.P489= | Silent (SNP) | VAF 57/194 reads (29%) | catalogued as rs140531239; called by muse, mutect2, varscan2
- MICALL2 | c.540G>A p.A180= | Silent (SNP) | VAF 55/169 reads (33%) | catalogued as rs375192105; called by muse, mutect2, varscan2
- NLRP2 | c.1908C>T p.D636= | Silent (SNP) | VAF 108/451 reads (24%) | catalogued as rs774830526, COSV54755539; called by muse, mutect2, varscan2
- OR10G8 | c.9C>T p.N3= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs1276314044, COSV70908448; called by muse, mutect2, varscan2
- OR8B3 | c.813A>G p.K271= | Silent (SNP) | VAF 35/196 reads (18%) | called by muse, mutect2, varscan2
- PCLO | c.11814T>A p.P3938= | Silent (SNP) | VAF 58/338 reads (17%) | called by muse, mutect2, varscan2
- PRKCB | c.1149C>T p.D383= | Silent (SNP) | VAF 97/280 reads (35%) | catalogued as rs543064850, COSV57784864; called by muse, mutect2, varscan2
- SLITRK4 | c.2229T>A p.I743= | Silent (SNP) | VAF 57/91 reads (63%) | called by muse, mutect2, varscan2
- TCHHL1 | c.354T>C p.D118= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs1321540281; called by muse, mutect2, varscan2
- TRABD2B | c.1461C>T p.P487= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs776291330; called by muse, mutect2, varscan2
- UGT2B4 | c.1482T>G p.T494= | Silent (SNP) | VAF 100/325 reads (31%) | catalogued as rs527905109; called by muse, mutect2, varscan2
- XIRP2 | c.735G>A p.R245= (on ENST00000628543; = p.R420= on NM_152381.6) | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- ZNF653 | c.87G>T p.A29= | Silent (SNP) | VAF 45/137 reads (33%) | called by muse, mutect2, varscan2
- ATP6V0A4 | c.1181-22G>A | Intron (SNP) | VAF 27/150 reads (18%) | catalogued as rs771330173; called by muse, mutect2, varscan2
- GOLGA8S | c.348+25G>A | Intron (SNP) | VAF 19/214 reads (9%) | catalogued as rs1330179118; called by muse, mutect2, varscan2
- PDE4C | c.472-38G>A | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- RPS8 | c.4+9C>T | Intron (SNP) | VAF 44/236 reads (19%) | catalogued as COSV63234354; called by muse, mutect2, varscan2
